Somatic mutation profile of tumor specimen 0DK3EC from CCDI case PBBXJB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.5 years (6,386 days).
Specimen 0DK3EC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d3c1891-755b-4bcf-a8fa-e5f898afca6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK3EP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cccda5f-e320-49da-895c-75fcd54d175a

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Intron 2, Splice Region 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 147/440 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 370/480 reads (77%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, varscan2
- HTRA4 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 248/790 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769279631, COSV56761082; called by muse, varscan2
- KDM4E | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 214/574 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs781841565; called by muse, varscan2
- MYO1F | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 187/581 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs778366731; called by muse, varscan2
- PIGR | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 342/1014 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV62903179; called by muse, varscan2
- RYR1 | c.2682G>A p.P894= | Splice Region (SNP) | VAF 142/548 reads (26%) | catalogued as rs919322708, CS149904, COSV62089204, COSV62109305; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, varscan2
- SYNE1 | c.17150A>G p.E5717G (on ENST00000367255 / NM_182961.4; = p.E5646G on NM_033071.3) | Missense Mutation (SNP) | VAF 170/664 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs780396166; called by muse, varscan2
- THBS2 | c.-22G>A | Splice Region (SNP) | VAF 154/408 reads (38%) | called by muse, varscan2
- DMRTB1 | c.318C>T p.D106= | Silent (SNP) | VAF 150/439 reads (34%) | called by muse, varscan2
- MROH9 | c.1386A>G p.Q462= | Silent (SNP) | VAF 327/1072 reads (31%) | catalogued as COSV63011811; called by muse, varscan2
- SMARCD3 | c.873G>A p.V291= (on ENST00000262188 / NM_001003801.2; = p.V278= on NM_003078.4) | Silent (SNP) | VAF 252/672 reads (38%) | called by muse, varscan2
- SYTL3 | c.1650G>A p.L550= (on ENST00000611299 / NM_001242394.1; = p.L482= on NM_001009991.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 344/899 reads (38%) | called by muse, varscan2
- TLN2 | c.5979G>A p.L1993= | Silent (SNP) | VAF 174/554 reads (31%) | called by muse, varscan2
- ABCG5 | c.502-95G>A | Intron (SNP) | VAF 26/96 reads (27%) | called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/47 reads (13%) | called by muse, varscan2
- OR4F4 | c.*14G>A | 3'UTR (SNP) | VAF 20/90 reads (22%) | catalogued as rs758179892; called by muse, varscan2
